Somatic mutation profile of tumor specimen 0DEYDT from CCDI case PBBPGM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.2 years (68 days).
Specimen 0DEYDT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28183631-2638-4717-a696-37ab168bdaae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEYDK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83db2dc-b6d9-469e-99d2-495cfe2f7601

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 66/438 reads (15%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, varscan2
